OHSU case 4954 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79c2acd3-3b7d-4c34-89bd-b02834707e3c

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Chronic neutrophilic leukemia: ICD-O-3 morphology code: 9963/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.0 years (25,567 days); Days to last follow up: 450 days (1.2 years).

Biospecimens (1 sample)
- Sample 1061D: Tissue type: Tumor; Preservation method: Snap Frozen.
